Somatic mutation profile of tumor specimen TCGA-JU-AAVI-01A (aliquot TCGA-JU-AAVI-01A-11D-A403-09) from TCGA case TCGA-JU-AAVI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 61.0 years (22,289 days).
Specimen TCGA-JU-AAVI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7960c867-c0f0-40d5-89d1-233913bdef07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JU-AAVI-10A (Blood Derived Normal), aliquot TCGA-JU-AAVI-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c99bc8f-2280-4920-a205-9ca43ce99082

The open-access MAF lists 52 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 13, Nonsense Mutation 4, Frame Shift Ins 2, Intron 2, In Frame Ins 1, RNA 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 35/62 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61652945; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.806G>A p.R269H (on ENST00000326195 / NM_001025091.2; = p.R231H on NM_001090.3) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as rs1236470926, COSV58227959; called by muse, mutect2, varscan2
- ADCY2 | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs368291995; called by muse, mutect2, varscan2
- AHNAK | c.10310G>T p.G3437V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.818); catalogued as COSV57223164, COSV99948812; called by muse, mutect2, varscan2
- ALPK2 | c.4565G>A p.G1522E | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV100864653; called by muse, mutect2, varscan2
- APOB | c.6761C>A p.T2254N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.726); catalogued as COSV99267008; called by muse, mutect2
- CBLN4 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 27/101 reads (27%) | catalogued as COSV50352790, COSV99290662; called by muse, mutect2, varscan2
- DUSP16 | c.1354T>C p.S452P | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV99963314; called by muse, mutect2, varscan2
- ERCC2 | c.2023G>A p.G675S | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM950364, COSV67267039, COSV67269069; called by muse, mutect2
- FHL5 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs763962962, COSV100459638; called by muse, mutect2, varscan2
- FHOD3 | c.2313G>C p.K771N (on ENST00000359247 / NM_001281739.3; = p.K788N on NM_025135.5) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV57184136; called by muse, mutect2, varscan2
- FOXO3 | c.440C>G p.P147R | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.63); catalogued as rs1471924689, COSV100670075; called by muse, mutect2, varscan2
- GDAP2 | c.1111C>G p.L371V | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.306); catalogued as rs780934017, COSV101032071; called by muse, mutect2, varscan2
- HDX | c.1827T>C p.N609= | Splice Region (SNP) | VAF 17/146 reads (12%) | catalogued as COSV99947808; called by muse, mutect2, varscan2
- IRAK1 | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs781948620, COSV100889035; called by muse, mutect2, varscan2
- KIF5C | c.2566G>A p.A856T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1044306642, COSV101276183; called by muse, mutect2, varscan2
- MAGEC1 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV99594844; called by muse, mutect2, varscan2
- MUC15 | c.854T>G p.L285* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99846584; called by muse, mutect2
- NRK | c.1654C>A p.Q552K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99688706; called by muse, mutect2, varscan2
- OSMR | c.1817C>T p.T606I | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as rs1052531211, COSV99953515; called by muse, mutect2, varscan2
- PGM1 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1453920894, COSV64301276; called by muse, mutect2, varscan2
- PRTN3 | c.444C>G p.H148Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as COSV99311620; called by muse, mutect2
- PTPRD | c.154A>T p.R52* | Nonsense Mutation (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100645986; called by muse, mutect2, varscan2
- RALB | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV55604768; called by muse, mutect2, varscan2
- RANBP3L | c.32A>T p.H11L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.298); catalogued as COSV99683973; called by muse, mutect2, varscan2
- SOHLH1 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs768925087, COSV100040381; called by muse, mutect2, varscan2
- TEKT2 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs369864150, COSV99255591; called by muse, mutect2, varscan2
- TMC5 | c.1655G>A p.R552Q (on ENST00000396229 / NM_001105248.1; = p.R306Q on NM_024780.5) | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as rs753207644, COSV54906844; called by muse, mutect2, varscan2
- TRAK1 | c.1517G>A p.R506Q (on ENST00000327628 / NM_001349247.2; = p.R448Q on NM_014965.5) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as rs770532586, COSV58256487, COSV58261372; called by mutect2, varscan2
- ZDHHC17 | c.1037C>A p.S346* | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | catalogued as COSV100602208, COSV58354501; called by muse, mutect2, varscan2
- DTX4 | c.1191_1196dup p.L398_Q399insHL | In Frame Ins (INS) | VAF 10/29 reads (34%) | called by mutect2, varscan2
- PCDHB9 | c.2221G>A p.G741S | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- PITPNM2 | c.2773del p.L925Cfs*34 | Frame Shift Del (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel*, varscan2
- PYGB | c.87dup p.K30Efs*82 | Frame Shift Ins (INS) | VAF 7/85 reads (8%) | called by mutect2, pindel, varscan2
- ZNF292 | c.6021dup p.Q2008Tfs*9 | Frame Shift Ins (INS) | VAF 23/133 reads (17%) | called by mutect2, pindel, varscan2
- ARHGEF2 | c.1119C>T p.A373= (on ENST00000361247 / NM_001162383.2; = p.A345= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs539613231, COSV100560916; called by muse, mutect2, varscan2
- C19orf12 | c.249G>A p.P83= (on ENST00000392278 / NM_001031726.3; = p.P72= on NM_031448.6) | Silent (SNP) | VAF 32/216 reads (15%) | catalogued as rs202054484, COSV100080540, COSV60364816; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- CCDC40 | c.2130C>T p.T710= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV100884299; called by muse, mutect2, varscan2
- CELSR2 | c.3828C>T p.C1276= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- CTNND2 | c.1398C>T p.S466= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as rs1316786685, COSV58913714; called by muse, mutect2
- CUBN | c.5685G>A p.L1895= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV100913217; called by muse, mutect2
- IRX1 | c.282G>A p.S94= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs769262251, COSV57361661, COSV57362428; called by muse, mutect2
- KNL1 | c.2619T>C p.I873= (on ENST00000346991 / NM_170589.5; = p.I847= on NM_144508.5) | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100706801, COSV61159962; called by muse, mutect2, varscan2
- MYCBPAP | c.2538G>A p.K846= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99277194; called by muse, mutect2, varscan2
- NPHP3 | c.3207A>C p.G1069= | Silent (SNP) | VAF 29/88 reads (33%) | catalogued as COSV100447198; called by muse, mutect2, varscan2
- SLC2A7 | c.1389C>T p.Y463= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs746573210, COSV101280823; called by muse, mutect2, varscan2
- SOAT2 | c.645G>A p.P215= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as rs1286056950, COSV100037573; called by muse, mutect2
- WDR13 | c.411G>A p.V137= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV99489533; called by muse, mutect2, varscan2
- FAM86C1P | n.148C>G | RNA (SNP) | VAF 10/250 reads (4%) | catalogued as rs1281149168, COSV100660773; called by muse, mutect2
- WNK1 | c.2140-3261C>T | Intron (SNP) | VAF 23/52 reads (44%) | catalogued as rs200794710; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF783 | c.802+3145C>T | Intron (SNP) | VAF 4/19 reads (21%) | catalogued as rs997203936, COSV65185394; called by muse, mutect2, varscan2
